Surgical pathology report (de-identified scan), TCGA case TCGA-P5-A733, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Cureline, specimen TCGA-P5-A733-01A (Primary Tumor).

ICD-O-3
Astrocytoma, grade II 9400/3
Site Brain, supratentorial NOS
C71.0
JL 8/15/13

Case #

Patient: **Age (years):** **Gender:**

Clinical diagnosis: Brain tumor

Date of procurement:

Sample:

Gross description:

Received material presented by gray - yellow pieces of left frontal lobe

Microscopic description:

Received material is represented by brain tissue consistent with diffuse astrocytoma; polymorphism of the nuclei. Ki-67 up to 5%

Final diagnosis: Diffuse astrocytoma: Grade II

Confidential

7/25/13

ICDPA Discrepancy		

Source: NCI Genomic Data Commons file b90bea2a-31fc-418e-a0d2-85700737295c (TCGA-P5-A733.4F732BEF-ADE0-4381-8D60-FB0034115C6D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).